Somatic mutation profile of tumor specimen TCGA-C5-A1MQ-01A (aliquot TCGA-C5-A1MQ-01A-11D-A14W-08) from TCGA case TCGA-C5-A1MQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 35.1 years (12,836 days).
Specimen TCGA-C5-A1MQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 010a152f-71b8-4711-8961-f92f9aed9eb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MQ-10A (Blood Derived Normal), aliquot TCGA-C5-A1MQ-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fdd0220-3e9d-4dec-9f38-713b717f07af

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 23, Silent 13, Nonsense Mutation 8, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EVC2 | c.2620C>T p.R874* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs760382778, CM092415, COSV60387825; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.2982G>C p.M994I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101166097, COSV67126076; called by muse, mutect2, varscan2
- ADAR | c.3020G>C p.G1007A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52712126; called by muse, mutect2, varscan2
- AGBL5 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59935504; called by muse, mutect2, varscan2
- AGBL5 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 39/160 reads (24%) | catalogued as COSV59935526; called by muse, mutect2, varscan2
- AGBL5 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV59935533; called by muse, varscan2
- AGBL5 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 62/215 reads (29%) | catalogued as COSV59935553; called by muse, varscan2
- AGBL5 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59935560; called by muse, varscan2
- ARHGEF12 | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV63102563; called by muse, varscan2
- ARHGEF37 | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.43); catalogued as COSV61367910; called by muse, mutect2
- ARIH2 | c.327C>G p.Y109* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV62703851; called by muse, mutect2, varscan2
- BAIAP3 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV60977258; called by muse, mutect2, varscan2
- CCT8 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99725903; called by muse, mutect2
- CD84 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs544642873, COSV60866805; called by muse, varscan2
- CIAO3 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52402177, COSV99284663; called by muse, mutect2
- CR1L | c.1529G>C p.R510T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.898); catalogued as COSV54322564; called by muse, mutect2, varscan2
- DALRD3 | c.548C>T p.S183L (on ENST00000341949 / NM_001009996.3; = p.S16L on NM_018114.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV58243946; called by muse, mutect2, varscan2
- GTF3C5 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938098283, COSV59601857; called by muse, mutect2, varscan2
- H3C6 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV64519400, COSV64519670; called by muse, mutect2, varscan2
- IGSF9B | c.2519A>G p.E840G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as rs749314712, COSV58063868; called by muse, mutect2, varscan2
- LRP2 | c.367A>T p.S123C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); catalogued as COSV99787297; called by muse, mutect2
- MCM7 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 121/445 reads (27%) | catalogued as rs758325786, COSV57993915; called by muse, mutect2, varscan2
- MYADM | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.295); catalogued as COSV61238570; called by muse, mutect2, varscan2
- MYO15A | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs766784099, COSV52750970; called by muse, mutect2, varscan2
- NEXMIF | c.1700C>T p.T567I | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50021813; called by muse, mutect2, varscan2
- PKHD1 | c.8119G>T p.G2707C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61860547, COSV61877100; called by muse, mutect2, varscan2
- PLIN4 | c.2573C>T p.A858V (on ENST00000301286; = p.A873V on NM_001367868.2) | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100013340; called by muse, mutect2
- RNASEH1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | catalogued as COSV59438019; called by muse, mutect2
- RYR2 | c.8875G>C p.E2959Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs770657610, COSV63662039, COSV63684077; called by muse, mutect2
- TMEM207 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.461); catalogued as COSV61561364; called by muse, mutect2, varscan2
- PTPRC | c.381_396del p.F127Lfs*35 | Frame Shift Del (DEL) | VAF 34/209 reads (16%) | called by mutect2, pindel, varscan2
- RACK1 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- RASAL2 | c.1782_1797del p.F594Lfs*18 | Frame Shift Del (DEL) | VAF 48/376 reads (13%) | called by mutect2, pindel
- AC008676.3 | c.534C>T p.L178= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs760704939, COSV100400465, COSV56635785; called by muse, mutect2, varscan2
- AGBL5 | c.876G>A p.L292= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV59935540; called by muse, varscan2
- AGBL5 | c.948G>A p.L316= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV59935546; called by muse, mutect2, varscan2
- ARHGAP11A | c.1305G>A p.L435= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100853205; called by muse, mutect2
- B3GNT9 | c.834C>T p.Y278= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV54625539; called by muse, mutect2, varscan2
- BRF1 | c.1638C>T p.L546= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs780154408, COSV59265937; called by muse, mutect2, varscan2
- CARD11 | c.2970G>A p.Q990= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs1239031867, COSV67796864, COSV67803346; called by muse, mutect2, varscan2
- KCTD12 | c.270C>T p.R90= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs751329210, COSV58524279; called by muse, mutect2, varscan2
- MDGA1 | c.2472C>T p.L824= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as rs773376284, COSV99776594; called by muse, mutect2, varscan2
- MYH3 | c.3669C>T p.S1223= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs1462373593, COSV56860914; called by muse, mutect2, varscan2
- PLA2G3 | c.381G>A p.G127= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99311464; called by muse, mutect2
- PLXNA1 | c.3426C>T p.T1142= | Silent (SNP) | VAF 49/193 reads (25%) | catalogued as rs774595798, COSV52522180; called by muse, mutect2, varscan2
- SRSF8 | c.714C>T p.S238= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV71665500; called by muse, mutect2, varscan2
